Somatic mutation profile of tumor specimen BA2033D (aliquot aq-BA2033D) from BEATAML1.0 case 2432, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.0 years (26,283 days).
Specimen BA2033D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 718676f9-5352-43ba-b3e6-ed9fcd9b370d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2632D (Solid Tissue Normal), aliquot aq-BA2632D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2f9e4bb-c6ee-423a-a6a2-10738d475da5

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDIAS | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1476429168; called by muse, mutect2, varscan2
- DNAH5 | c.9969G>A p.M3323I | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs866722646; called by muse, mutect2
- PES1 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1283492897; called by muse, mutect2, varscan2
- STAM2 | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); catalogued as rs1227724350; called by mutect2, varscan2
- EBAG9 | c.179G>A p.W60* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- FAM200A | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LCA5L | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCN15 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PARD6B | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2
- PLA2G6 | c.895-4G>T | Splice Region (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- PLXNC1 | c.724_740dup p.Y248Afs*58 | Frame Shift Ins (INS) | VAF 40/111 reads (36%) | called by mutect2, varscan2
- RPS6 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ZBTB14 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- ESYT1 | c.2514G>A p.S838= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs771690344; called by muse, mutect2, varscan2
- GASK1A | c.654G>A p.E218= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- KRTAP24-1 | c.276T>G p.S92= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs780691889; called by muse, mutect2, varscan2
- MAGEC2 | c.1092C>T p.V364= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- MICAL2 | c.3334+52C>T | Intron (SNP) | VAF 8/15 reads (53%) | catalogued as rs757470970; called by muse, varscan2
